Somatic mutation profile of tumor specimen TCGA-R6-A6XG-01B (aliquot TCGA-R6-A6XG-01B-11D-A33E-09) from TCGA case TCGA-R6-A6XG, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G2; Age at diagnosis: 64.3 years (23,484 days).
Specimen TCGA-R6-A6XG-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60c4230b-c11f-4889-acfe-08b1d1ad4a05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R6-A6XG-10A (Blood Derived Normal), aliquot TCGA-R6-A6XG-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1569888c-fe3c-468c-9389-4b9ea1badc62

The open-access MAF lists 212 somatic variants for this specimen: 144 protein-altering or splice-affecting, 59 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 59, Nonsense Mutation 7, Frame Shift Del 4, Intron 4, RNA 2, In Frame Del 2, 3'UTR 2, In Frame Ins 1, Frame Shift Ins 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>A p.G598E | Missense Mutation (SNP) | VAF 23/62 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51769031, COSV51808387; called by muse, mutect2, varscan2
- AHCTF1 | c.6404G>A p.R2135Q (on ENST00000366508; = p.R2109Q on NM_015446.5) | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs752425265; called by muse, mutect2, varscan2
- ALPK3 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs558339788; called by muse, mutect2, varscan2
- ANGPT2 | c.979C>G p.R327G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV57336274; called by muse, mutect2, varscan2
- ARF5 | c.456G>T p.T152= | Splice Region (SNP) | VAF 7/36 reads (19%) | catalogued as COSV50000699; called by muse, mutect2, varscan2
- ASTN1 | c.274T>G p.F92V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV56071108; called by muse, mutect2, varscan2
- BAG2 | c.73T>C p.S25P | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs775112624; called by muse, mutect2, varscan2
- BTN2A1 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 45/111 reads (41%) | catalogued as rs552017766, COSV100438435, COSV57006395; called by muse, mutect2, varscan2
- C16orf74 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs377716191, COSV99411667; called by muse, mutect2, varscan2
- C16orf78 | c.134A>C p.K45T | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV54556384, COSV54556736; called by muse, mutect2, varscan2
- CAPNS1 | c.279C>A p.N93K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV55823439; called by muse, mutect2, varscan2
- CCR4 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs762113496, COSV58381447; called by muse, mutect2, varscan2
- COL1A2 | c.2504G>A p.G835D | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51958909; called by muse, mutect2, varscan2
- COL6A2 | c.2917G>T p.V973L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs145959270; called by muse, mutect2, varscan2
- CSMD1 | c.6581C>T p.T2194M (on ENST00000520002; = p.T2193M on NM_033225.6) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1022424286; called by muse, mutect2, varscan2
- DBF4 | c.74dup p.N25Kfs*11 | Frame Shift Ins (INS) | VAF 90/208 reads (43%) | catalogued as rs762918884; called by mutect2, varscan2
- DNAJC1 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.47); PolyPhen benign (0.119); catalogued as rs756409994, COSV65376005; called by muse, mutect2, varscan2
- DPH1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs200134501; called by muse, mutect2, varscan2
- EMC2 | c.704C>G p.S235W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV55207742; called by muse, mutect2, varscan2
- FAM47C | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 146/178 reads (82%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.515); catalogued as rs144392292, COSV63724213; called by muse, mutect2, varscan2
- FBXL4 | c.982T>C p.Y328H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs772370168; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABBR2 | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 66/83 reads (80%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.063); catalogued as rs368856308, COSV52295857; ClinVar: likely benign; called by muse, mutect2, varscan2
- HERC2 | c.8666A>C p.E2889A | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55316936; called by muse, mutect2, varscan2
- IGLV3-21 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 104/202 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs371481989; called by muse, mutect2, varscan2
- KIAA1549L | c.4633C>T p.P1545S (on ENST00000321505; = p.P1842S on NM_012194.3) | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750958641; called by muse, mutect2, varscan2
- LATS2 | c.1663G>T p.D555Y | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV66874422; called by muse, mutect2, varscan2
- LRRC4B | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs762762398, COSV100975918; called by muse, mutect2, varscan2
- MAEL | c.1158C>A p.S386R | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV63305698; called by muse, mutect2, varscan2
- MAP2 | c.2579C>T p.T860M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs772124563, COSV52288249; called by muse, mutect2, varscan2
- MIDEAS | c.1703C>T p.T568I | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs745599939; called by muse, mutect2, varscan2
- MPP2 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs146765164; called by muse, mutect2, varscan2
- MRC1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 135/409 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1041177555; called by muse, mutect2, varscan2
- MRPL55 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs375373877; called by muse, mutect2, varscan2
- MRPS33 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763797933; called by muse, mutect2, varscan2
- MUC5AC | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 81/90 reads (90%) | SIFT deleterious (0.01); catalogued as rs747696530; called by muse, mutect2, varscan2
- NLGN4X | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs770584895; called by muse, mutect2, varscan2
- NPFFR1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.738); catalogued as rs866841512; called by muse, mutect2, varscan2
- NRXN1 | c.4202C>T p.T1401M | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs201871400, COSV60501078; called by muse, mutect2, varscan2
- OGFOD3 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1441414407, COSV57340740; called by muse, mutect2, varscan2
- PALD1 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs141292267; called by muse, mutect2, varscan2
- PCDHB16 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 58/66 reads (88%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV53361604; called by muse, mutect2, varscan2
- PCDHGB4 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs762866893, COSV53953630; called by muse, mutect2, varscan2
- PCED1B | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.051); catalogued as rs1279810981, COSV71395259; called by muse, mutect2, varscan2
- PLCL1 | c.2470C>T p.R824W | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70836267; called by muse, mutect2, varscan2
- POGK | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs1164819994; called by muse, mutect2, varscan2
- PRRC2A | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs758316360; called by muse, mutect2, varscan2
- PTPRK | c.3325G>C p.D1109H (on ENST00000368215 / NM_001291984.2; = p.D1110H on NM_002844.4) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV63895161; called by muse, mutect2, varscan2
- RAVER1 | c.1807C>T p.R603W (on ENST00000615032; = p.A729V on NM_133452.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as rs1472248343; called by muse, mutect2, varscan2
- RSPH10B | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769772155; called by mutect2, varscan2
- SFRP2 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56837892; called by muse, mutect2, varscan2
- SGSM1 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.098); catalogued as COSV68511245; called by muse, mutect2, varscan2
- SLITRK5 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1188705024, COSV61522517; called by muse, mutect2, varscan2
- SMOC2 | c.1192G>A p.V398M (on ENST00000356284 / NM_001166412.2; = p.V409M on NM_022138.3) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs754482354, COSV62439085; called by muse, mutect2, varscan2
- SPTA1 | c.1924A>G p.K642E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as COSV63760144; called by muse, mutect2, varscan2
- TADA2B | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.404); catalogued as rs1560395529, COSV53827266; called by muse, mutect2, varscan2
- TNIP3 | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1260358666; called by muse, mutect2, varscan2
- TNR | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs546435742, COSV54868251; called by muse, mutect2, varscan2
- TRPV4 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs373108373, COSV55682601; called by muse, mutect2, varscan2
- TSHZ3 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs200738522, COSV53667763, COSV53669143, COSV53674591; called by muse, mutect2, varscan2
- UGT1A10 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs770761874; called by muse, mutect2
- USP29 | c.1796A>C p.K599T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs1312798231, COSV54145084; called by muse, mutect2, varscan2
- VAV3 | c.2114A>G p.E705G | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs781755295; called by muse, mutect2, varscan2
- VPS4A | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs759385403, COSV54751201; called by muse, mutect2, varscan2
- ZFAT | c.3542C>T p.T1181M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.894); catalogued as rs577332990; called by mutect2, varscan2
- ZMYM1 | c.2600G>A p.R867Q | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs764025094; called by muse, mutect2, varscan2
- ACSM5 | c.401C>G p.A134G | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- APBB1 | c.1011del p.T338Rfs*2 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- ARHGAP17 | c.1510G>C p.D504H | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- ASAH2 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- BCAS4 | c.346C>G p.R116G | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2
- C1QTNF7 | c.72A>C p.K24N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- C8orf34 | c.890A>T p.K297I | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CACNG8 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CCDC183 | c.732C>A p.N244K | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- CD1C | c.152A>C p.D51A | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2
- CD1D | c.599A>T p.K200M | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDC7 | c.624_629dup p.E209_L210dup | In Frame Ins (INS) | VAF 12/62 reads (19%) | called by mutect2, varscan2
- CDH8 | c.1268G>T p.S423I | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- CFAP100 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHM | c.907A>G p.M303V | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHN1 | c.412A>T p.T138S | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- CNTLN | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- DACT3 | c.1724G>A p.W575* | Nonsense Mutation (SNP) | VAF 16/22 reads (73%) | called by muse, mutect2
- DCBLD1 | c.875T>G p.L292R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- DIAPH3 | c.2669G>A p.C890Y (on ENST00000400324 / NM_001042517.2; = p.C627Y on NM_030932.3) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJC2 | c.713_715del p.A238del | In Frame Del (DEL) | VAF 38/91 reads (42%) | called by mutect2, pindel, varscan2
- ECEL1 | c.1655A>G p.K552R | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EPPK1 | c.4532C>T p.A1511V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- EVI5 | c.1377del p.F459Lfs*5 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by mutect2, pindel, varscan2
- FAM13C | c.1485A>C p.E495D | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- FBN3 | c.6704T>C p.V2235A | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- FOS | c.1105T>C p.S369P | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FRAS1 | c.8239G>A p.G2747S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FZD2 | c.1510A>G p.I504V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.013); called by muse, mutect2
- GRM1 | c.1991T>G p.V664G | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GSTCD | c.1741C>T p.L581F (on ENST00000360505 / NM_001031720.3; = p.L494F on NM_024751.3) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- HCFC2 | c.1746G>T p.E582D | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- HEXIM1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HJV | c.796C>T p.Q266* (on ENST00000336751 / NM_213653.4; = p.Q153* on NM_145277.5) | Nonsense Mutation (SNP) | VAF 71/214 reads (33%) | called by muse, mutect2, varscan2
- HPGDS | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HUWE1 | c.6265A>T p.I2089F | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ICMT | c.655T>G p.W219G | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IFI27L2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- IFT140 | c.2894T>G p.L965R | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- IGF2R | c.5141A>T p.K1714I | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- IGHV3-30 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- IL4R | c.1873A>G p.S625G | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- ITGAM | c.1501A>T p.R501W (on ENST00000648685 / NM_001145808.2; = p.R500W on NM_000632.4) | Missense Mutation (SNP) | VAF 32/401 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IZUMO1R | c.165C>A p.C55* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- KCNMA1 | c.1859+1G>A p.X620_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- KMT2D | c.8009C>T p.S2670F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- LRRC6 | c.1348A>G p.S450G | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MACC1 | c.769C>G p.P257A | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MAF | c.1066T>C p.F356L | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MUC5B | c.12523C>T p.R4175C | Missense Mutation (SNP) | VAF 126/159 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- N4BP1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NPHS1 | c.2828C>T p.P943L | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR4C11 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- OR8H3 | c.529T>A p.F177I | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCDH15 | c.38C>A p.S13* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- PEAR1 | c.3083C>T p.P1028L | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2
- PIK3CB | c.1043C>T p.T348I | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- POTED | c.77A>G p.K26R | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); called by mutect2, varscan2
- PRAMEF1 | c.1135C>A p.L379I | Missense Mutation (SNP) | VAF 191/350 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PSG1 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 96/399 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- PSG11 | c.692del p.V231Afs*3 | Frame Shift Del (DEL) | VAF 72/375 reads (19%) | called by mutect2, pindel, varscan2
- PTPN14 | c.261C>A p.D87E | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PYGO1 | c.592C>A p.P198T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SEMA6D | c.2830C>T p.R944* (on ENST00000316364 / NM_153618.2; = p.R882* on NM_020858.2) | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- SERPINE2 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- SLCO1B3 | c.412A>C p.S138R | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SNX32 | c.204_238del p.W69Rfs*15 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | called by mutect2, pindel
- STK33 | c.632C>G p.S211* | Nonsense Mutation (SNP) | VAF 48/61 reads (79%) | called by muse, mutect2, varscan2
- TTN | c.66557C>A p.P22186H (on ENST00000591111; = p.P14762H on NM_003319.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBA3C | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TUSC2 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- UTP3 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ZBED1 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZCWPW2 | c.996_1013del p.K332_C338delinsN | In Frame Del (DEL) | VAF 42/124 reads (34%) | called by mutect2, pindel, varscan2
- ZFP30 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF461 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZNF496 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); called by muse, mutect2
- ZNF559-ZNF177 | c.349A>C p.T117P | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF627 | c.461T>C p.F154S | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ABCA10 | c.2457G>A p.P819= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as rs1196251007, COSV52218390; called by muse, mutect2, varscan2
- ADAP2 | c.570G>A p.E190= | Silent (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- ADAR | c.3243C>T p.C1081= | Silent (SNP) | VAF 48/102 reads (47%) | called by muse, mutect2, varscan2
- AGAP2 | c.702C>T p.V234= | Silent (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- BEND6 | c.396C>A p.L132= | Silent (SNP) | VAF 25/121 reads (21%) | called by muse, mutect2, varscan2
- BMP15 | c.1077G>A p.P359= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs147148606, COSV53141696; called by muse, mutect2
- CATSPERB | c.1035T>A p.P345= | Silent (SNP) | VAF 77/140 reads (55%) | called by muse, mutect2, varscan2
- CBLN4 | c.150G>A p.T50= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1295945825; called by muse, mutect2, varscan2
- CCDC88A | c.5310G>A p.A1770= (on ENST00000436346 / NM_001365480.1; = p.A1742= on NM_018084.5) | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as rs770508534; called by muse, mutect2, varscan2
- CEP78 | c.672C>T p.D224= | Silent (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- CLIP2 | c.2286G>A p.K762= | Silent (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- DAAM2 | c.1443G>A p.R481= | Silent (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- DCT | c.1473T>C p.A491= | Silent (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- DNAH3 | c.2730G>T p.T910= | Silent (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- DNAJC13 | c.4674A>T p.L1558= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- ENPP5 | c.528A>G p.S176= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs1210879315; called by muse, mutect2, varscan2
- GPAT2 | c.1188C>T p.G396= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as rs746992961; called by muse, mutect2, varscan2
- GPR39 | c.1173G>A p.P391= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs761843800; called by muse, mutect2, varscan2
- GRIN2A | c.3969T>C p.N1323= | Silent (SNP) | VAF 117/198 reads (59%) | catalogued as COSV100409434; called by muse, mutect2, varscan2
- GSTT2B | c.243G>A p.P81= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1291087188; called by mutect2, varscan2
- HABP2 | c.756C>T p.D252= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs142304622; called by muse, mutect2, varscan2
- HAS1 | c.177C>T p.Y59= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1019343918; called by muse, mutect2
- HMCN1 | c.6528A>T p.A2176= | Silent (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- HSPA6 | c.537G>A p.T179= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as rs370722659; called by muse, mutect2, varscan2
- IDH3B | c.1125T>G p.S375= | Silent (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- IL7R | c.900T>G p.P300= | Silent (SNP) | VAF 36/43 reads (84%) | called by muse, mutect2, varscan2
- JMJD1C | c.3897G>A p.Q1299= | Silent (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- LARGE1 | c.1293G>A p.Q431= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs764546586; called by muse, mutect2, varscan2
- LHX8 | c.129C>T p.D43= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- LRWD1 | c.1929C>T p.I643= | Silent (SNP) | VAF 15/214 reads (7%) | catalogued as rs752806384; called by muse, mutect2
- MACF1 | c.8316C>T p.S2772= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs777497979, COSV57125655, COSV99243958; called by muse, mutect2, varscan2
- MAP3K7 | c.507A>T p.T169= | Silent (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
- MNDA | c.766T>C p.L256= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV63740041; called by muse, mutect2, varscan2
- MUC16 | c.28392T>G p.T9464= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as rs751502909; called by muse, mutect2, varscan2
- MYO18B | c.3067T>C p.L1023= | Silent (SNP) | VAF 50/74 reads (68%) | catalogued as COSV59144921; called by muse, mutect2, varscan2
- NOS2 | c.2238G>A p.P746= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs778148076, COSV100569450; called by muse, mutect2, varscan2
- NRIP3 | c.678T>G p.P226= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs934031581; called by muse, mutect2, varscan2
- OR52A5 | c.427T>C p.L143= | Silent (SNP) | VAF 78/96 reads (81%) | catalogued as COSV56613991, COSV56614404; called by muse, mutect2, varscan2
- ORMDL3 | c.78C>T p.Y26= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs916219256; called by muse, mutect2, varscan2
- PCDH10 | c.2487C>T p.S829= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV52091098; called by muse, mutect2, varscan2
- PCDHGA2 | c.2226C>T p.G742= | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as rs1278697431, COSV53985011; called by muse, mutect2, varscan2
- PCDHGA8 | c.1407C>A p.A469= | Silent (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1554C>T p.D518= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- PNPLA6 | c.3057C>T p.I1019= (on ENST00000414982 / NM_001166111.2; = p.I971= on NM_006702.5) | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs746522719, COSV55381019; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRR23B | c.474C>T p.D158= | Silent (SNP) | VAF 56/172 reads (33%) | catalogued as COSV61495024; called by muse, mutect2, varscan2
- RASL10B | c.90C>T p.S30= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as rs1480654179; called by muse, mutect2, varscan2
- SH3GL2 | c.99C>T p.F33= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as rs750499767; called by muse, mutect2, varscan2
- SHANK3 | c.3456G>A p.P1152= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs764295916; called by muse, mutect2, varscan2
- SNTG1 | c.651T>C p.S217= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- SSH1 | c.699G>A p.T233= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs201601911; called by muse, mutect2, varscan2
- TBC1D13 | c.654C>T p.Y218= | Silent (SNP) | VAF 86/108 reads (80%) | catalogued as rs749651808, COSV56355592; called by muse, mutect2, varscan2
- TBXA2R | c.846G>C p.L282= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- TENM3 | c.1440C>T p.A480= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs760373925, COSV69312174; called by muse, mutect2, varscan2
- TG | c.8106G>A p.E2702= | Silent (SNP) | VAF 44/187 reads (24%) | called by muse, mutect2, varscan2
- TMX3 | c.945A>C p.S315= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7654C>T p.L2552= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- ZNF48 | c.759C>A p.P253= | Silent (SNP) | VAF 14/157 reads (9%) | called by muse, mutect2
- ZNF581 | c.576G>A p.T192= | Silent (SNP) | VAF 48/225 reads (21%) | catalogued as rs1239431578, COSV54402277; called by muse, mutect2, varscan2
- ZNF81 | c.1638C>A p.T546= | Silent (SNP) | VAF 17/17 reads (100%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*708A>C | 3'UTR (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- BAD | c.188-5116G>T | Intron (SNP) | VAF 32/96 reads (33%) | called by muse, mutect2, varscan2
- CFAP206 | c.1494+11T>A | Intron (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- DUSP13 | c.*127G>A | 3'UTR (SNP) | VAF 26/87 reads (30%) | catalogued as rs576003204; called by muse, mutect2, varscan2
- IGF2 | c.326-502C>A | Intron (SNP) | VAF 6/55 reads (11%) | catalogued as rs1178789799; called by muse, mutect2
- MAP2 | c.5074-2056A>C | Intron (SNP) | VAF 21/76 reads (28%) | catalogued as COSV52291917; called by muse, mutect2, varscan2
- MIR200A | n.46C>T | RNA (SNP) | VAF 125/192 reads (65%) | called by muse, mutect2, varscan2
- MIR495 | n.52A>C | RNA (SNP) | VAF 16/31 reads (52%) | called by mutect2, varscan2
- TRAV36DV7 | chr14:22221902 C>G | 5'Flank (SNP) | VAF 13/32 reads (41%) | called by muse, varscan2
